Somatic mutation profile of tumor specimen MP2PRT-PASLIU-TMP1-A (aliquot MP2PRT-PASLIU-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASLIU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (856 days).
Specimen MP2PRT-PASLIU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c58770dd-fdc2-4c5d-9b95-f19e91449b4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLIU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLIU-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b17e646-f305-42b1-95d9-82febd913514

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 12, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 89/335 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KIAA1549L | c.3581C>T p.T1194M (on ENST00000321505; = p.T1491M on NM_012194.3) | Missense Mutation (SNP) | VAF 169/390 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs558635917, COSV55771747; called by muse, mutect2
- RPE | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 17/399 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV100627038; called by muse, mutect2
- SYTL4 | c.510G>C p.K170N | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.136); catalogued as COSV52172629; called by muse, mutect2
- ZNF208 | c.2227C>T p.H743Y | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs527498161, COSV68113318, COSV68114627; called by muse, mutect2, varscan2
- ZNF697 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 218/592 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101360029; called by muse, mutect2, varscan2
- AEBP1 | c.3244G>C p.E1082Q | Missense Mutation (SNP) | VAF 207/566 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ATOH1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 136/428 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); called by muse, varscan2
- CATSPER2 | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- IKZF1 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 16/532 reads (3%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.989); called by muse, mutect2
- LRPAP1 | c.278G>A p.W93* | Nonsense Mutation (SNP) | VAF 171/393 reads (44%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TACC3 | c.374A>C p.D125A | Missense Mutation (SNP) | VAF 19/423 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2
- BTK | c.1248G>A p.V416= | Silent (SNP) | VAF 190/282 reads (67%) | called by muse, mutect2, varscan2
- CBWD5 | c.114C>T p.L38= | Silent (SNP) | VAF 24/790 reads (3%) | catalogued as rs1282262901; called by muse, mutect2
- GRM4 | c.1899C>T p.I633= | Silent (SNP) | VAF 178/524 reads (34%) | catalogued as COSV100946079; called by muse, mutect2, varscan2
- H2AC13 | c.282C>T p.L94= | Silent (SNP) | VAF 82/206 reads (40%) | catalogued as COSV100704386, COSV62440799; called by muse, mutect2, varscan2
- KCNK9 | c.660C>T p.Y220= | Silent (SNP) | VAF 152/380 reads (40%) | catalogued as rs111826894, COSV57280572; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCART1 | c.1491G>A p.A497= | Silent (SNP) | VAF 352/866 reads (41%) | catalogued as rs1266312607; called by muse, mutect2, varscan2
- SLC45A2 | c.700C>T p.L234= | Silent (SNP) | VAF 145/462 reads (31%) | called by muse, mutect2, varscan2
